Gene-level copy-number profile of tumor specimen TCGA-04-1357-01A from TCGA case TCGA-04-1357, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 52.0 years (18,999 days).
Specimen TCGA-04-1357-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.934ee741-d185-47f2-860c-74e90af24b4e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1357-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b07c4786-293a-4f61-8c82-61bfe878d50c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 470; copy number 2: 11,972; copy number 3: 26,884; copy number 4: 12,551; copy number 5: 5,402; copy number 6: 2,043; copy number 7: 495.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1357-01A-01D-0452-01): tumor purity 0.52, ploidy 3.31, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 495 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:126,776,623–128,189,677, 24 genes, copy number 7 (within-gene range 6–7): LMNB1, MARCHF3, C5orf63, AC005915.1, MRPS5P3, AC011416.1, SELENOTP2, AC011416.2, AC011416.3, AC011416.4, MEGF10, AC010424.1, AC010424.2, HNRNPKP1, PRRC1, AC010424.3, CTXN3, AC022118.1, CCDC192, CUL1P1, AC068658.1, LINC01184, SLC12A2, KDELC1P1.
- chr7:111,726,110–112,481,017, 13 genes, copy number 7 (within-gene range 4–7): DOCK4, AC003077.1, DOCK4-AS1, RNA5SP237, AC003080.1, ZNF277, RN7SKP187, AC004112.1, MTND5P8, MTND6P24, MTCYBP24, IFRD1, AC079741.1.
- chr7:112,450,487–112,450,645, 1 gene, copy number 7: AC079741.2.
- chr8:127,253,213–145,066,685, 339 genes, copy number 7 (broad region; genes not listed).
- chr12:66,347,431–73,208,317, 118 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 470. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
